Somatic mutation profile of tumor specimen TCGA-AL-3466-01A (aliquot TCGA-AL-3466-01A-01D-1252-08) from TCGA case TCGA-AL-3466, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 41.6 years (15,181 days).
Specimen TCGA-AL-3466-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d66c6e60-b8ff-4a8e-aa07-4b186bed927c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AL-3466-10A (Blood Derived Normal), aliquot TCGA-AL-3466-10A-01D-1252-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fbd94742-dc09-41b4-acdb-6ebee5a58cdc

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 22, Silent 8, In Frame Del 2, Nonsense Mutation 2, Frame Shift Del 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CA10 | c.953T>G p.L318R | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV53362006; called by muse, mutect2, varscan2
- COQ8B | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs1245757407; called by muse, mutect2
- EPG5 | c.2144dup p.S716Vfs*46 | Frame Shift Ins (INS) | VAF 33/153 reads (22%) | catalogued as rs1344466516; called by mutect2, pindel, varscan2
- FAM124B | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs756001279, COSV54739186; called by muse, mutect2, varscan2
- HDAC8 | c.937C>G p.R313G | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV65266136; called by muse, mutect2, varscan2
- M6PR | c.453+2T>C p.X151_splice | Splice Site (SNP) | VAF 16/94 reads (17%) | catalogued as rs1239648677; called by muse, varscan2
- MEIS2 | c.1182G>T p.Q394H | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.001); catalogued as COSV54931899; called by muse, mutect2, varscan2
- NOS3 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774609359; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 56/463 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as rs1463924478; called by muse, mutect2, varscan2
- SLC35F3 | c.1187A>T p.E396V (on ENST00000366617 / NM_001300845.1; = p.E465V on NM_173508.4) | Missense Mutation (SNP) | VAF 33/250 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV64020997; called by muse, mutect2, varscan2
- TTC30B | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 98/785 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs748258271; called by muse, mutect2, varscan2
- TTC6 | c.1481G>A p.R494H (on ENST00000267368; = p.R1860H on NM_001310135.3) | Missense Mutation (SNP) | VAF 79/125 reads (63%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs151288389; called by muse, mutect2, varscan2
- AKNA | c.361A>G p.T121A | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HAVCR1 | c.229_239del p.Y77Gfs*19 | Frame Shift Del (DEL) | VAF 61/282 reads (22%) | called by mutect2, pindel, varscan2
- MED12L | c.2368C>T p.L790F | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MS4A12 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 45/289 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NIBAN1 | c.1651G>T p.D551Y | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- OXR1 | c.2218T>A p.Y740N (on ENST00000442977 / NM_001198532.1; = p.Y712N on NM_018002.3) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PFKFB4 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 49/116 reads (42%) | called by muse, mutect2, varscan2
- PIK3C2A | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 57/264 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP4R2 | c.384T>A p.N128K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- PTPN14 | c.1939A>G p.N647D | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RPTN | c.1773A>G p.I591M | Missense Mutation (SNP) | VAF 213/738 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- SASS6 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- TMC8 | c.1743_1772del p.G582_L591del | In Frame Del (DEL) | VAF 40/491 reads (8%) | called by mutect2, pindel
- TPR | c.1437_1439del p.S480del | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- TTN | c.86570C>T p.A28857V (on ENST00000591111; = p.A21433V on NM_003319.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | PolyPhen probably damaging (0.997); called by muse, mutect2
- VWCE | c.2323G>T p.E775* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- ZNF681 | c.1502C>T p.T501I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BRINP1 | c.1404G>A p.S468= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as rs370346617, COSV56296653; called by muse, mutect2, varscan2
- CRISPLD2 | c.1443G>A p.L481= | Silent (SNP) | VAF 57/272 reads (21%) | called by muse, mutect2, varscan2
- GTPBP4 | c.543G>A p.K181= | Silent (SNP) | VAF 193/429 reads (45%) | catalogued as COSV62551706; called by muse, mutect2, varscan2
- H2BC13 | c.282G>A p.E94= | Silent (SNP) | VAF 137/188 reads (73%) | called by muse, mutect2, varscan2
- IGHV1-46 | c.237C>T p.Y79= | Silent (SNP) | VAF 102/161 reads (63%) | catalogued as rs555653722; called by muse, mutect2, varscan2
- MLIP | c.396T>C p.I132= | Silent (SNP) | VAF 117/152 reads (77%) | called by muse, mutect2, varscan2
- MTARC1 | c.714G>A p.R238= | Silent (SNP) | VAF 115/478 reads (24%) | catalogued as rs1255106650; called by muse, mutect2, varscan2
- NGFR | c.801G>T p.V267= | Silent (SNP) | VAF 54/335 reads (16%) | called by muse, mutect2, varscan2
